Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94J, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94J-01A (Primary Tumor).

Collect date: .
(MM/DD/YYYY)

ICD O-3

Mixed germ cell tumor
9085/3

Site B Testis NOS
862.9

7/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

1-"Right testis":

Mixed germ cell tumor with the following components:

Immature teratoma (40%), with areas of carcinomatous transformation in the form of squamous cell carcinoma (focal area); yolk sac tumor (40%); embryonal carcinoma (10%) and seminoma (10%). Presence of multiple areas of necrosis and infiltration of tunica albuginea.

Epididymis and spermatic cord absent of neoplastic invasion.

2-"Nodule of left testis (next to epididymis tail) – nodule 1":

Mixed germ cell tumor, non-seminomatous, with the components teratoma and embryonal carcinoma in this sample.

3-"Left intratesticular nodule – nodule 2":

Immature teratoma.

Primary / Tumor Site Discrepancy		☒
ICD O-3 Discrepancy		☒
Qual/Syncronous Prima. / Noted	☒	☒

Source: NCI Genomic Data Commons file e3f0dbb7-32d7-4f07-9a22-111a97452b6b (TCGA-YU-A94J-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).